Somatic mutation profile of tumor specimen TCGA-HC-7745-01A (aliquot TCGA-HC-7745-01A-11D-2114-08) from TCGA case TCGA-HC-7745, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-HC-7745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51148651-46c4-4cf4-b93c-39eaef2d9b25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7745-10A (Blood Derived Normal), aliquot TCGA-HC-7745-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f57e910-3ead-4845-98d7-ccbe3fdc34f1

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 14, Silent 8, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCE1 | c.698A>C p.Q233P | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56846260, COSV56848339; called by muse, mutect2
- ACTC1 | c.154A>C p.K52Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV51760445; called by muse, mutect2, varscan2
- ASMT | c.727C>T p.P243S (on ENST00000381229; = p.P271S on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67110202; called by muse, mutect2
- CLEC1B | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237872141, COSV53725393, COSV53726050; called by muse, mutect2, varscan2
- DNAH8 | c.4092A>T p.R1364S | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59468054; called by muse, mutect2, varscan2
- EHHADH | c.475T>G p.L159V | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as COSV51632062; called by muse, mutect2, varscan2
- ELAVL2 | c.667A>G p.N223D | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs1416580522, COSV56367399; called by muse, mutect2, varscan2
- GPR4 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59917799; called by muse, mutect2, varscan2
- HTR2C | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1556423301, COSV52200520, COSV52219834; called by muse, mutect2, varscan2
- LRRC66 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV58635702; called by muse, mutect2, varscan2
- OR10J1 | c.606T>G p.S202R | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV71129291; called by muse, mutect2, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs751873496; called by mutect2, varscan2
- PRKCB | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV57792388; called by muse, mutect2, varscan2
- SLF1 | c.2121+2T>G p.X707_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | catalogued as COSV54372192; called by muse, mutect2, varscan2
- STT3A | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67065277; called by muse, mutect2, varscan2
- WDR49 | c.577G>A p.A193T (on ENST00000308378 / NM_001366158.1; = p.A534T on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs747124354, COSV57713277; called by muse, mutect2, varscan2
- CYP2W1 | c.387G>A p.T129= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs753258511, COSV58269385; called by muse, mutect2, varscan2
- DOP1B | c.3606C>T p.L1202= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV67694859; called by mutect2, varscan2
- EXOC8 | c.1917G>A p.L639= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV50479037; called by muse, mutect2, varscan2
- FADS1 | c.945G>A p.P315= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as rs1054304450, COSV63520947; called by muse, mutect2, varscan2
- FLG | c.4554T>C p.H1518= | Silent (SNP) | VAF 71/504 reads (14%) | catalogued as rs1327330199, COSV64245489; called by muse, mutect2, varscan2
- MESP1 | c.747T>G p.A249= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV55588551; called by muse, mutect2, varscan2
- NNT | c.2934T>G p.A978= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV52928025; called by muse, mutect2, varscan2
- PRKG2 | c.1260C>T p.S420= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs774332995, COSV52329101; called by muse, mutect2, varscan2
